TCGA case TCGA-06-0154 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/24ae6f30-eec8-49a7-abde-246b3873679e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 424 days (1.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 54.8 years (20,018 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mivobulin Isethionate; Treatment intent type: Adjuvant; Days to treatment start: 12 days; Days to treatment end: 89 days; Number of cycles: 4; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 98 days; Days to treatment end: 145 days; Treatment dose: 5,940 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Treatment intent type: Adjuvant; Days to treatment start: 160 days; Days to treatment end: 191 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 235 days; Days to treatment end: 235 days; Number of cycles: 1; Treatment dose: 8 Wafer; Prescribed dose: 8; Prescribed dose units: Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 321 days; Days to treatment end: 321 days; Treatment dose: 1,500 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Initial disease status: Progressive Disease; Days to treatment start: 373 days (1.0 years); Treatment dose: 150 mg; Prescribed dose: 100; Prescribed dose units: mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 55.4 years (20,226 days); Days to diagnosis: 208 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 235 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Day 208 (post initial treatment): Progression or recurrence: Yes; Days to progression: 208 days.
- Days to follow up: 389 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 424 days (1.2 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0154-01A-01-BS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20.
  Slide TCGA-06-0154-01A-02-BS2: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 50; Percent stromal cells: 0.
  Slide TCGA-06-0154-01A-03-BS3: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 50; Percent stromal cells: 0.
- Sample TCGA-06-0154-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0154-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Pharmaceutical therapy drug name: Gliadel wafer.
- Drug treatment 2, Route of administrations: Route of administration: Intum.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: CI 980.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Radiation treatment 1: Radiation type other: Stereotactic Radiosurgery.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 424 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 424 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 208 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0154-01A-03D-0236-01): tumor purity 0.71, ploidy 1.99, whole-genome doublings 0.
